Somatic mutation profile of tumor specimen C3N-02436-01 (aliquot CPT0115530009) from CPTAC case C3N-02436, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 51.8 years (18,937 days).
Specimen C3N-02436-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ed86a54-f4eb-4b4f-8f6d-eefca5cafc8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02436-32 (Blood Derived Normal), aliquot CPT0116420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3be29c2c-2e5a-4d4a-8ec2-abb9c29ad779

The open-access MAF lists 1,602 somatic variants for this specimen: 1,107 protein-altering or splice-affecting, 282 silent, 213 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 728, Silent 282, Frame Shift Del 253, Intron 94, Frame Shift Ins 49, 3'UTR 35, Nonsense Mutation 31, RNA 29, 5'UTR 25, In Frame Del 17, 5'Flank 15, 3'Flank 15.

Variants (750 of 1,602; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 69/273 reads (25%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACADVL | c.1316del p.G439Vfs*5 | Frame Shift Del (DEL) | VAF 110/340 reads (32%) | catalogued as rs748077880; ClinVar: pathogenic; called by mutect2, varscan2
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 55/180 reads (31%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 91/269 reads (34%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL18A1 | c.2082dup p.V695Rfs*18 (on ENST00000359759 / NM_130444.3; = p.V460Rfs*18 on NM_030582.4) | Frame Shift Ins (INS) | VAF 68/247 reads (28%) | catalogued as rs760175310; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EIF2B5 | c.967C>T p.R323C (on ENST00000647909; = p.R315C on NM_003907.3) | Missense Mutation (SNP) | VAF 131/404 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs113994063, CM013536, CM041320, COSV56606437; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 119/415 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 77/324 reads (24%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2D | c.14710C>T p.R4904* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs398123721, CM105476, COSV56414273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 67/228 reads (29%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTCH1 | c.114dup p.L39Afs*51 | Frame Shift Ins (INS) | VAF 72/233 reads (31%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 53/212 reads (25%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 77/284 reads (27%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SERPINA1 | c.1158dup p.E387Rfs*14 | Frame Shift Ins (INS) | VAF 58/226 reads (26%) | catalogued as rs764325655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SLC46A1 | c.194del p.G65Afs*25 | Frame Shift Del (DEL) | VAF 63/202 reads (31%) | catalogued as rs80338769, CD073700; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMARCB1 | c.932C>T p.T311I (on ENST00000263121; = p.T357I on NM_003073.5) | Missense Mutation (SNP) | VAF 185/629 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555881567; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 165/452 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs587782596, CM920672, COSV52689134, COSV53283559, COSV53738947; ClinVar: pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AACS | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.544); catalogued as rs200646490, COSV55538764; called by muse, mutect2, varscan2
- ABCA10 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV52221192; called by muse, mutect2, varscan2
- ABCB6 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417519007, COSV54693095; called by muse, mutect2, varscan2
- AC004832.3 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 167/477 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as rs777112870; called by muse, varscan2
- AC004922.1 | c.1832T>C p.L611P | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV53165207; called by muse, mutect2, varscan2
- ACCSL | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101122346; called by muse, mutect2, varscan2
- ACP4 | c.343_344del p.S115Cfs*33 | Frame Shift Del (DEL) | VAF 81/356 reads (23%) | catalogued as rs1344787574; called by pindel, varscan2
- ACP7 | c.670del p.D224Ifs*154 | Frame Shift Del (DEL) | VAF 85/297 reads (29%) | catalogued as rs763396774; called by mutect2, pindel, varscan2
- ACTA2 | c.5G>A p.C2Y | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs750805652; called by muse, mutect2, varscan2
- ACTL7A | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as rs144590040; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD2 | c.568del p.Q190Rfs*11 (on ENST00000315906 / NM_001145400.2; = p.Q262Rfs*11 on NM_139174.4) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1390126889; called by mutect2, pindel, varscan2
- ADAMTS19 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as rs751563795; called by muse, mutect2, varscan2
- ADCY3 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745597461, COSV53166565; called by muse, mutect2, varscan2
- ADCY6 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as rs753912669; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 64/202 reads (32%) | catalogued as rs760256806, COSV59443632; called by mutect2, varscan2
- ADGRB1 | c.4346C>T p.P1449L | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs925283142, COSV60096797; called by muse, mutect2, varscan2
- ADGRL3 | c.1276C>T p.P426S (on ENST00000506720 / NM_001322402.2; = p.P358S on NM_015236.6) | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72267970; called by muse, mutect2, varscan2
- ADGRL3 | c.4093G>A p.A1365T (on ENST00000506720 / NM_001322402.2; = p.A1254T on NM_015236.6) | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.182); catalogued as rs749889713, COSV72230669; called by muse, mutect2, varscan2
- AFDN | c.4904G>T p.R1635L (on ENST00000447894 / NM_001366320.1; = p.R1633L on NM_001040000.3) | Missense Mutation (SNP) | VAF 94/310 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100652458; called by muse, mutect2, varscan2
- AFF3 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1350738249; called by muse, mutect2, varscan2
- AGAP3 | c.2488G>A p.G830S (on ENST00000622464; = p.G866S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 186/612 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs368589847; called by muse, mutect2, varscan2
- AGO1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs773153331, COSV64595181; called by muse, mutect2, varscan2
- AGPAT1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 19/642 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61247313; called by muse, mutect2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 40/146 reads (27%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1C2 | c.740del p.K247Sfs*8 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs1554772819; called by mutect2, varscan2
- AKR1C3 | c.740del p.K247Sfs*8 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs1554786256; called by mutect2, varscan2
- ANKDD1A | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs748170837; called by muse, mutect2, varscan2
- ANKH | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs566488014, COSV52487642; called by muse, mutect2, varscan2
- ANKRD2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1176394244; called by muse, mutect2, varscan2
- AP002748.5 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 194/596 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs759763673, COSV59152593; called by muse, mutect2, varscan2
- APBB2 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371817559; called by muse, mutect2, varscan2
- APMAP | c.328+1del p.X110_splice | Splice Site (DEL) | VAF 56/151 reads (37%) | catalogued as rs754512895; called by pindel, varscan2
- ARHGAP33 | c.387del p.E130Rfs*64 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as rs772293323; called by mutect2, pindel, varscan2
- ARHGEF17 | c.4538C>T p.S1513L | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1035019659; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | catalogued as rs1295666772; called by mutect2, pindel, varscan2
- ARR3 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs752871927, COSV52105236; called by muse, mutect2, varscan2
- ARRB2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs780961076, COSV52618024; called by muse, mutect2, varscan2
- ARSG | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756314416, COSV71592753; called by muse, mutect2, varscan2
- ART1 | c.735dup p.F246Lfs*2 | Frame Shift Ins (INS) | VAF 83/274 reads (30%) | catalogued as rs762428866; called by mutect2, varscan2
- ASCL1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 164/443 reads (37%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1046623355; called by muse, varscan2
- ASPHD2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as rs140657637; called by muse, mutect2, varscan2
- ATAD3B | c.431C>T p.T144M (on ENST00000308647; = p.T250M on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs777052416, COSV58019146; called by muse, mutect2, varscan2
- ATG16L1 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs753271055; called by muse, mutect2, varscan2
- ATP1A2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs796052278, COSV63404484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 157/450 reads (35%) | catalogued as rs772363145; called by mutect2, varscan2
- ATR | c.6335G>A p.R2112H | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs535888898, COSV63385977; called by muse, mutect2, varscan2
- ATRX | c.2247_2249del p.S750del | In Frame Del (DEL) | VAF 61/198 reads (31%) | catalogued as rs1297294136; called by pindel, varscan2
- BCAN | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs546794419; called by muse, mutect2, varscan2
- BEND4 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as rs868863881; called by muse, mutect2, varscan2
- BNC1 | c.2504C>T p.T835M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs757018655, COSV61759373; called by muse, mutect2, varscan2
- BOC | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs773561274; called by muse, mutect2, varscan2
- BOD1L2 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.03); catalogued as rs1221574711; called by muse, mutect2, varscan2
- BRD1 | c.1468del p.A490Pfs*26 | Frame Shift Del (DEL) | VAF 51/186 reads (27%) | catalogued as COSV53458006; called by mutect2, pindel, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- C12orf40 | c.202+1G>T p.X68_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as rs1180403206; called by muse, mutect2, varscan2
- C19orf57 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs569609896, COSV100694905; called by muse, mutect2, varscan2
- C1orf105 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62959954; called by muse, mutect2, varscan2
- C20orf202 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV68763718; called by muse, mutect2, varscan2
- C3orf52 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV99332608; called by muse, mutect2, varscan2
- C4orf45 | c.539del p.K180Rfs*10 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs761567622; called by mutect2, pindel, varscan2
- C4orf54 | c.1080dup p.K361Qfs*12 | Frame Shift Ins (INS) | VAF 20/114 reads (18%) | catalogued as rs753377943; called by mutect2, varscan2
- C5orf34 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs746690868, COSV60928857; called by muse, mutect2, varscan2
- C6orf132 | c.3112C>T p.R1038C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs931623940; called by muse, mutect2, varscan2
- C6orf62 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65290459; called by muse, mutect2, varscan2
- CACNA1G | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778008575; called by muse, mutect2, varscan2
- CACNA2D4 | c.1934del p.P645Lfs*58 | Frame Shift Del (DEL) | VAF 22/141 reads (16%) | catalogued as rs767503914; called by mutect2, pindel, varscan2
- CACNB3 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764262320, COSV99975046; called by muse, mutect2, varscan2
- CAD | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs190254898; called by muse, mutect2, varscan2
- CARD10 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99324992, COSV99325435; called by muse, mutect2, varscan2
- CASKIN2 | c.2993A>G p.E998G | Missense Mutation (SNP) | VAF 133/398 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs906466929; called by muse, mutect2, varscan2
- CASKIN2 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs978077636; called by muse, varscan2
- CASR | c.2747C>T p.T916M (on ENST00000490131; = p.T993M on NM_000388.4) | Missense Mutation (SNP) | VAF 186/603 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs758227966, COSV56136619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPER1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs1379432582; called by muse, mutect2, varscan2
- CBX8 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197801603; called by muse, mutect2, varscan2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC47 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs745411083; called by muse, mutect2, varscan2
- CCDC80 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs755474141, COSV52815360, COSV52818504; called by muse, mutect2, varscan2
- CCDC97 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs567042490, COSV54189948; called by muse, mutect2, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs781790231; called by mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH10 | c.1152del p.F384Lfs*23 | Frame Shift Del (DEL) | VAF 61/231 reads (26%) | catalogued as COSV100051875; called by mutect2, pindel, varscan2
- CDK13 | c.2205del p.V736Yfs*32 | Frame Shift Del (DEL) | VAF 54/170 reads (32%) | catalogued as rs780713745; called by mutect2, varscan2
- CDK5RAP2 | c.4109_4111del p.F1370del | In Frame Del (DEL) | VAF 71/267 reads (27%) | catalogued as rs1218266553; called by pindel, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs753494539; called by mutect2, varscan2
- CEMIP2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs368636488, COSV65489979; called by muse, varscan2
- CENPA | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV51983153; called by muse, mutect2, varscan2
- CEP131 | c.2140G>A p.E714K (on ENST00000269392 / NM_001319228.2; = p.E711K on NM_014984.4) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs532103664; called by muse, mutect2, varscan2
- CEP170 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766467060, COSV60515094; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 55/212 reads (26%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.1846_1848del p.K616del | In Frame Del (DEL) | VAF 38/154 reads (25%) | catalogued as rs1363903162; called by pindel, varscan2
- CERT1 | c.264dup p.T89Hfs*27 | Frame Shift Ins (INS) | VAF 75/198 reads (38%) | catalogued as rs893362976; called by mutect2, varscan2
- CFAP126 | c.227del p.P76Lfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs780823798; called by mutect2, pindel
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 95/289 reads (33%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFDP1 | c.157del p.R53Efs*18 | Frame Shift Del (DEL) | VAF 29/146 reads (20%) | catalogued as rs1296337835; called by mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD8 | c.5783G>A p.R1928Q (on ENST00000646647 / NM_001170629.2; = p.R1649Q on NM_020920.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as rs1450857291, COSV63036549, COSV63037457; called by muse, mutect2, varscan2
- CHERP | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV52225554; called by muse, mutect2
- CHST13 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV60042078; called by muse, mutect2, varscan2
- CLEC14A | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100643685; called by muse, mutect2, varscan2
- CLIP3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 113/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394561930, COSV62111881; called by muse, mutect2, varscan2
- CLRN3 | c.262del p.T88Lfs*5 | Frame Shift Del (DEL) | VAF 95/356 reads (27%) | catalogued as rs748191748; called by mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 75/194 reads (39%) | catalogued as rs751921758; called by mutect2, varscan2
- CNOT3 | c.983dup p.P329Afs*68 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs1320255270; called by mutect2, pindel, varscan2
- COIL | c.192del p.L65Sfs*11 | Frame Shift Del (DEL) | VAF 101/335 reads (30%) | catalogued as rs763239843; called by mutect2, pindel, varscan2
- COL21A1 | c.1893del p.G632Efs*8 | Frame Shift Del (DEL) | VAF 30/151 reads (20%) | catalogued as rs1319692854; called by mutect2, pindel, varscan2
- COL2A1 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.984); catalogued as rs755207565, COSV61535003; called by muse, mutect2
- COL5A3 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763576120, COSV99319372; called by muse, mutect2, varscan2
- COQ8A | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 128/623 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781751337; called by mutect2, varscan2
- CPNE5 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs755375011; called by muse, mutect2, varscan2
- CRAMP1 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771116293, COSV51962786; called by muse, mutect2, varscan2
- CREBBP | c.4120G>A p.G1374R | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs747582040; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 67/216 reads (31%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRTC2 | c.818del p.G273Afs*29 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | catalogued as rs771895874; called by mutect2, pindel, varscan2
- CTAG2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV55995831; called by muse, mutect2
- CUX1 | c.161C>G p.A54G (on ENST00000292535 / NM_181552.4; = p.A65G on NM_001913.5) | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs143267032, COSV52897999; called by muse, mutect2, varscan2
- CYP7B1 | c.392del p.N131Ifs*4 | Frame Shift Del (DEL) | VAF 59/210 reads (28%) | catalogued as rs748480664, COSV59597772; called by mutect2, pindel, varscan2
- DAB2IP | c.2578C>A p.H860N (on ENST00000408936; = p.H832N on NM_032552.3) | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52255184; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBF4B | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs780737091; called by muse, mutect2, varscan2
- DCAF4L2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 136/472 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs752302400, COSV60476978, COSV60484022; called by muse, mutect2, varscan2
- DDX23 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100339945; called by muse, mutect2, varscan2
- DDX24 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs759757010, COSV58213293; called by muse, mutect2, varscan2
- DGKD | c.622C>T p.R208C (on ENST00000264057 / NM_152879.3; = p.R164C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369141889; called by muse, mutect2, varscan2
- DHRS12 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.975); catalogued as rs907638921; called by muse, mutect2
- DHX15 | c.1618C>A p.L540M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as COSV100391114; called by muse, mutect2, varscan2
- DIDO1 | c.2953C>T p.R985C | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as rs767665547; called by muse, mutect2, varscan2
- DIS3 | c.2032del p.I678Ffs*59 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | catalogued as rs771690280; called by mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DISP3 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs771271771, COSV53832144; called by muse, mutect2, varscan2
- DLGAP2 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs34274599, COSV70097003; called by muse, mutect2, varscan2
- DNAH14 | c.9856C>T p.R3286C (on ENST00000445597; = p.R4294C on NM_001367479.1) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs755140486; called by muse, mutect2, varscan2
- DNAH3 | c.12224G>A p.R4075H | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774870350; called by muse, mutect2
- DNAJC16 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs1355551260, COSV101012568; called by muse, mutect2, varscan2
- DNM1 | c.2434del p.A812Rfs*76 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs747024881; called by mutect2, varscan2
- DOCK8 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 146/489 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs573775959, COSV101210119; called by muse, mutect2, varscan2
- DRD2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100669385; called by muse, mutect2
- DSEL | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1369863233, COSV59492074; called by muse, mutect2, varscan2
- DST | c.21916G>A p.A7306T (on ENST00000361203 / NM_001374722.1; = p.A4979T on NM_015548.5) | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771999169, COSV99758147; called by muse, mutect2, varscan2
- DTX2 | c.1508G>A p.C503Y | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs772055212, COSV56860171; called by muse, mutect2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs758962538; called by mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs746509911; called by mutect2, varscan2
- EDA | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.375); catalogued as rs1233934840; called by muse, mutect2, varscan2
- EDF1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1310339050, COSV56377229; called by muse, mutect2, varscan2
- EFNB1 | c.629-2A>C p.X210_splice | Splice Site (SNP) | VAF 112/374 reads (30%) | catalogued as CS041531; called by muse, mutect2, varscan2
- EFNB2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 108/328 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs1305239957, COSV55365247; called by muse, mutect2, varscan2
- EIF4G1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1560210274, COSV100071490; called by muse, mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 44/139 reads (32%) | catalogued as rs1290746509; called by mutect2, pindel, varscan2
- ELFN1 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1273292018; called by muse, mutect2, varscan2
- ELK1 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99901924; called by muse, mutect2, varscan2
- ELOVL5 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439920; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as rs770453803; called by mutect2, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 47/168 reads (28%) | catalogued as rs746682537; called by mutect2, varscan2
- ENO4 | c.1029del p.H345Tfs*21 (on ENST00000622726; = p.H342Tfs*21 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 136/393 reads (35%) | catalogued as rs1156693659; called by mutect2, varscan2
- ENPP3 | c.45_47del p.K15del | In Frame Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs1317058080; called by pindel, varscan2
- ENTPD6 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs376104648; called by muse, mutect2, varscan2
- EPB41L4A | c.885del p.F295Lfs*35 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs1157347372; called by mutect2, pindel, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPCAM | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs749805135; called by muse, mutect2, varscan2
- EPHB4 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1328611138, COSV62270373; called by muse, mutect2, varscan2
- ESYT2 | c.676C>T p.R226W (on ENST00000613624; = p.R150W on NM_020728.3) | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs541054812; called by muse, mutect2, varscan2
- ESYT3 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs554792770, COSV101272627; called by muse, mutect2, varscan2
- EYS | c.704G>A p.W235* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as CM153010, COSV100675934; called by muse, mutect2, varscan2
- F10 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs758980620, CM043485, COSV65022381; called by muse, mutect2, varscan2
- F9 | c.1187G>A p.C396Y | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852273, CM940679, CM940680, CM990578, COSV99496170; called by muse, mutect2, varscan2
- FAM120A | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763086084, COSV52905437; called by muse, mutect2
- FAM178B | c.421del p.Q141Rfs*3 | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | catalogued as rs1473925401; called by mutect2, pindel, varscan2
- FAM53B | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1410825842; called by muse, mutect2, varscan2
- FASTKD1 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs369291952; called by muse, mutect2, varscan2
- FAT1 | c.5630del p.P1877Lfs*20 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as COSV71676103; called by mutect2, pindel, varscan2
- FAT1 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs549553973, COSV71675102; called by muse, mutect2, varscan2
- FAT3 | c.2777del p.L926* | Frame Shift Del (DEL) | VAF 67/220 reads (30%) | catalogued as COSV53090267; called by mutect2, pindel, varscan2
- FBP2 | c.992G>A p.C331Y | Missense Mutation (SNP) | VAF 125/442 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1335716120; called by muse, mutect2, varscan2
- FCRL5 | c.1621T>C p.C541R | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774917517; called by muse, mutect2, varscan2
- FFAR1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1456826776; called by muse, mutect2, varscan2
- FGD2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); catalogued as rs374091470; called by muse, mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 54/189 reads (29%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGF21 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs139679302; called by muse, mutect2, varscan2
- FKBP11 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 118/362 reads (33%) | catalogued as rs778229387; called by muse, mutect2, varscan2
- FLG | c.9146G>A p.R3049H | Missense Mutation (SNP) | VAF 77/581 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1307149268; called by muse, mutect2, varscan2
- FLG | c.6577del p.T2193Hfs*226 | Frame Shift Del (DEL) | VAF 133/493 reads (27%) | catalogued as COSV100912393; called by mutect2, pindel, varscan2
- FLG2 | c.5675del p.G1892Afs*510 | Frame Shift Del (DEL) | VAF 107/421 reads (25%) | catalogued as COSV66167459; called by mutect2, pindel, varscan2
- FOS | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 134/359 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.416); catalogued as rs746175046, COSV57839163; called by muse, mutect2, varscan2
- FRMPD1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs200633175; called by muse, mutect2, varscan2
- FUT8 | c.538C>T p.R180W (on ENST00000360689 / NM_001371534.1; = p.R17W on NM_004480.4) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752943058; called by muse, mutect2, varscan2
- G3BP1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs765135383, COSV62365819; called by muse, mutect2, varscan2
- GALNS | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 175/486 reads (36%) | catalogued as rs1275386976, CM145589; called by muse, mutect2, varscan2
- GCN1 | c.5176G>A p.G1726S | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs764123227, COSV56113337; called by muse, mutect2, varscan2
- GIPC3 | c.685dup p.A229Gfs*10 | Frame Shift Ins (INS) | VAF 43/140 reads (31%) | catalogued as rs748150647; called by mutect2, varscan2
- GJA5 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs782627991, COSV54786591; called by muse, mutect2, varscan2
- GLUD2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs750535591, COSV60153107; called by muse, mutect2, varscan2
- GPAM | c.2251T>C p.Y751H | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs777208370; called by muse, mutect2, varscan2
- GPBAR1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs747205893; called by muse, mutect2
- GPLD1 | c.2221del p.L741* | Frame Shift Del (DEL) | VAF 59/187 reads (32%) | catalogued as rs749977099; called by mutect2, pindel, varscan2
- GPR143 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs985314593; called by muse, mutect2, varscan2
- GPRC5B | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 91/395 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs200955705, COSV56025220; called by muse, mutect2, varscan2
- GRAMD1C | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs970698305, COSV63982816; called by muse, mutect2, varscan2
- GRIN2B | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 158/430 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs150070901; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GRIN2D | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs777372732; called by muse, mutect2, varscan2
- GRIN2D | c.3788C>T p.P1263L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1168009425; called by muse, mutect2, varscan2
- GRIP1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 39/165 reads (24%) | catalogued as COSV54028453; called by muse, mutect2, varscan2
- GRK1 | c.148del p.L50Sfs*81 | Frame Shift Del (DEL) | VAF 100/325 reads (31%) | catalogued as COSV59554442; called by mutect2, pindel, varscan2
- GTPBP6 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 151/441 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368869165; called by muse, mutect2, varscan2
- HDAC11 | c.291dup p.V98Rfs*70 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | catalogued as rs754533859; called by mutect2, varscan2
- HDAC11 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 40/144 reads (28%) | catalogued as rs199560935; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs761197780; called by mutect2, varscan2
- HOXC12 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 164/529 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54535060; called by muse, mutect2, varscan2
- HPS1 | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs753983178, COSV57270672; called by muse, mutect2, varscan2
- HS3ST4 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58828313; called by muse, mutect2, varscan2
- HS3ST4 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 147/474 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753467285, COSV58805150; called by muse, mutect2, varscan2
- IBTK | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as rs757965458, COSV60390875, COSV60391556; called by muse, mutect2, varscan2
- IGF2R | c.6160G>A p.V2054I | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1449697283, COSV63630668; called by muse, mutect2, varscan2
- IGSF9 | c.2015C>T p.P672L (on ENST00000368094 / NM_001135050.2; = p.P656L on NM_020789.4) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs376264039, COSV63639573; called by muse, mutect2, varscan2
- IL36B | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749087744; called by muse, mutect2, varscan2
- INPP4A | c.1952C>T p.A651V (on ENST00000074304 / NM_001134224.1; = p.A612V on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV50786993; called by muse, mutect2, varscan2
- INTS6 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 49/139 reads (35%) | catalogued as rs750241474; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ISM2 | c.1052G>A p.R351Q (on ENST00000342219 / NM_199296.3; = p.G236S on NM_182509.4) | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.195); catalogued as rs1005045450, COSV53636509; called by muse, mutect2, varscan2
- ITGA11 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs377444249; called by muse, mutect2, varscan2
- ITGA3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 122/386 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs140781106, CM123820; called by muse, varscan2
- JCAD | c.1515del p.D507Mfs*23 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs770240166; called by mutect2, pindel, varscan2
- KAT6A | c.1175T>C p.F392S | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.157); catalogued as rs752852908; called by muse, mutect2, varscan2
- KCNA4 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs372809586; called by muse, mutect2, varscan2
- KCND2 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 10/187 reads (5%) | catalogued as rs1387288913, COSV58571832; called by muse, mutect2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs759860142; called by mutect2, varscan2
- KCTD20 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367786498; called by muse, mutect2, varscan2
- KDM5A | c.3479_3481del p.E1160del | In Frame Del (DEL) | VAF 46/150 reads (31%) | catalogued as rs760330652; called by pindel, varscan2
- KIAA1109 | c.10178G>A p.R3393H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756367377; called by muse, mutect2, varscan2
- KIAA1549 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs779260078; called by muse, mutect2, varscan2
- KIAA1549L | c.2308C>T p.R770C (on ENST00000321505; = p.R1067C on NM_012194.3) | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs368053850; called by muse, mutect2, varscan2
- KIF19 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373527071; called by muse, mutect2, varscan2
- KIF3B | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as rs759713888, COSV65226926; called by muse, mutect2, varscan2
- KLHDC7A | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 126/456 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs748284288, COSV68769634; called by muse, mutect2, varscan2
- KLHDC7A | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV68770471; called by muse, mutect2, varscan2
- KLHL36 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778327522; called by muse, mutect2, varscan2
- KLK10 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as rs772069381, COSV59398194; called by muse, mutect2, varscan2
- KLRF2 | c.178del p.M60Wfs*7 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs781664453; called by mutect2, pindel, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | catalogued as COSV55868319; called by pindel, varscan2
- KRCC1 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs959915012; called by muse, mutect2
- KRT83 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 248/790 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs778964859; ClinVar: uncertain significance; called by muse, varscan2
- KRT85 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 161/589 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs749177362; called by muse, mutect2, varscan2
- KRTAP10-8 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 249/830 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs143687357, COSV100554858; called by muse, mutect2, varscan2
- KRTAP4-11 | c.157del p.Q53Sfs*194 | Frame Shift Del (DEL) | VAF 132/639 reads (21%) | catalogued as COSV99063368; called by pindel, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 32/78 reads (41%) | catalogued as rs750491454; called by mutect2, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 63/241 reads (26%) | catalogued as rs782221297; called by mutect2, pindel, varscan2
- LNX1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99820859; called by muse, mutect2, varscan2
- LNX2 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs765099031, COSV60338768; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV100540885; called by mutect2, pindel, varscan2
- LRRC15 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs779111515; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- LRRTM3 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63664300; called by muse, mutect2, varscan2
- LTBP1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100617055; called by muse, mutect2, varscan2
- LTBP1 | c.4132G>A p.V1378M (on ENST00000404816 / NM_206943.4; = p.V1052M on NM_000627.4) | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs779579409; called by muse, mutect2, varscan2
- LTBP2 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 117/404 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as rs769155905, COSV56209676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs754757253, COSV52588935; called by mutect2, pindel, varscan2
- LUZP4 | c.285del p.K95Nfs*12 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as COSV64218370; called by mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB3 | c.465del p.A156Lfs*13 | Frame Shift Del (DEL) | VAF 57/190 reads (30%) | catalogued as rs34054171, COSV100854733; called by mutect2, varscan2
- MAGEE1 | c.1632del p.F544Lfs*5 | Frame Shift Del (DEL) | VAF 58/180 reads (32%) | catalogued as COSV100819313; called by mutect2, pindel, varscan2
- MAN2B1 | c.2354C>T p.T785M | Missense Mutation (SNP) | VAF 152/451 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as rs372011807; called by muse, mutect2, varscan2
- MAN2B1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55470847; called by muse, mutect2, varscan2
- MAP10 | c.562del p.E188Rfs*136 | Frame Shift Del (DEL) | VAF 73/236 reads (31%) | catalogued as rs1447426204; called by mutect2, pindel, varscan2
- MAP1A | c.1248del p.D417Tfs*48 | Frame Shift Del (DEL) | VAF 58/183 reads (32%) | catalogued as rs1449327112, COSV100289242; called by mutect2, varscan2
- MAP1B | c.5189del p.P1730Rfs*93 | Frame Shift Del (DEL) | VAF 68/208 reads (33%) | catalogued as COSV57098946; called by mutect2, pindel, varscan2
- MAP2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV52301738; called by muse, mutect2, varscan2
- MAP2K7 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs746875567, COSV67608665; called by muse, mutect2, varscan2
- MAPK9 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180924776; called by muse, mutect2, varscan2
- MAZ | c.39dup p.F14Lfs*34 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs767720617; called by mutect2, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 41/133 reads (31%) | catalogued as rs755716804, COSV56502366; called by mutect2, varscan2
- MBD5 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.951); catalogued as rs769480362, COSV101290095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED21 | c.433_434del p.*145Afs*17 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs748257158; called by mutect2, pindel, varscan2
- MEOX1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200747279; called by muse, mutect2, varscan2
- METTL16 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs199995697; called by muse, mutect2, varscan2
- METTL3 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1336492472, COSV52971692; called by muse, mutect2, varscan2
- MEX3B | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV61663081; called by muse, mutect2, varscan2
- MEX3D | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs772199152, COSV66312096; called by muse, mutect2, varscan2
- MGA | c.7190A>G p.K2397R (on ENST00000219905 / NM_001164273.1; = p.K2188R on NM_001080541.2) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99581136; called by muse, mutect2, varscan2
- MIB2 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.117); catalogued as rs1320029593; called by muse, mutect2, varscan2
- MLLT1 | c.1381dup p.Q461Pfs*23 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs772076449; called by mutect2, varscan2
- MMUT | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs764985110; called by muse, mutect2, varscan2
- MNS1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1428933655, COSV53068250; called by muse, mutect2, varscan2
- MRAP | c.107-4G>A | Splice Region (SNP) | VAF 53/470 reads (11%) | catalogued as rs747528868, COSV100353352; called by muse, mutect2, varscan2
- MUC5B | c.16003G>A p.A5335T | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs865930645, COSV101500625; called by muse, mutect2, varscan2
- MYBL1 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1160683792; called by muse, mutect2, varscan2
- MYH7 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 155/493 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs730880792, COSV100806114, COSV62515838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs776506361, COSV60614553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYNN | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530715265; called by muse, mutect2, varscan2
- MYO16 | c.4619C>T p.P1540L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as rs777772987, COSV62763381; called by muse, mutect2, varscan2
- MYO1C | c.1132C>T p.R378* (on ENST00000648651 / NM_001080779.2; = p.R343* on NM_033375.5) | Nonsense Mutation (SNP) | VAF 244/691 reads (35%) | catalogued as rs1444490796, COSV62998527; called by muse, mutect2, varscan2
- MYO3B | c.3443A>G p.Q1148R | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs756894438; called by muse, mutect2, varscan2
- NCAM2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.205); catalogued as rs372471672, COSV53055679; called by muse, mutect2, varscan2
- NCAPH2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as rs771068683; called by muse, mutect2, varscan2
- NCKAP5L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.355); catalogued as rs767225059, COSV100259287; called by muse, mutect2, varscan2
- NCOR1 | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs759642635, COSV51969533, COSV52001613; called by muse, mutect2, varscan2
- NELL2 | c.2096A>G p.Q699R | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs373966289; called by muse, mutect2, varscan2
- NEUROD2 | c.242del p.G81Efs*31 | Frame Shift Del (DEL) | VAF 63/217 reads (29%) | catalogued as COSV56910947; called by mutect2, pindel, varscan2
- NFKB1 | c.1417G>A p.E473K (on ENST00000394820 / NM_001382627.1; = p.E474K on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1337707554; called by muse, mutect2, varscan2
- NIPAL3 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs776518295; called by muse, mutect2, varscan2
- NIPBL | c.6233_6235del p.I2078del | In Frame Del (DEL) | VAF 42/174 reads (24%) | catalogued as rs1554031820; called by pindel, varscan2
- NLGN1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV64325767; called by muse, mutect2, varscan2
- NLN | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780180376, COSV66765937; called by muse, mutect2, varscan2
- NSD1 | c.6595C>T p.R2199C | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61770031; called by muse, mutect2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | catalogued as COSV55073962; called by mutect2, varscan2
- NUMA1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs774770988; called by muse, mutect2, varscan2
- NWD2 | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs200234605; called by muse, mutect2, varscan2
- OBSCN | c.11359G>A p.G3787R | Missense Mutation (SNP) | VAF 181/585 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs770911888; called by muse, mutect2, varscan2
- OBSL1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54729663; called by muse, mutect2, varscan2
- OLFML2B | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1200916804; called by muse, mutect2, varscan2
- OLR1 | c.69del p.A24Lfs*19 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | catalogued as rs747703868; called by mutect2, pindel, varscan2
- OR2C1 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV59240790; called by muse, mutect2, varscan2
- OR2L8 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV61726949; called by muse, mutect2
- OR2Y1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs776793152, COSV57136597; called by muse, mutect2, varscan2
- OR6M1 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs751873728; called by muse, mutect2, varscan2
- OSBPL6 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs200223014; called by muse, mutect2, varscan2
- OTOG | c.5954C>T p.T1985M | Missense Mutation (SNP) | VAF 175/562 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs868729716, COSV61129877; called by muse, mutect2, varscan2
- OTUD7A | c.1420del p.V474Cfs*62 (on ENST00000307050 / NM_001382637.1; = p.V467Cfs*62 on NM_130901.3) | Frame Shift Del (DEL) | VAF 76/245 reads (31%) | catalogued as COSV61036088; called by mutect2, pindel, varscan2
- OVOL2 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53859791; called by muse, mutect2, varscan2
- PADI2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs138940135; called by muse, mutect2, varscan2
- PADI6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs529584194, COSV100639873; called by muse, mutect2, varscan2
- PAFAH2 | c.243G>A p.V81= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as rs933897813; called by muse, varscan2
- PANX2 | c.1204del p.V402Cfs*29 | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | catalogued as COSV99348771; called by mutect2, pindel, varscan2
- PATL2 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55997128; called by muse, mutect2, varscan2
- PAX5 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1214797180; called by muse, varscan2
- PCDHA1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 264/816 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100974636, COSV65375836; called by muse, mutect2, varscan2
- PCDHA12 | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 24/628 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1487907484, COSV56497102; called by muse, mutect2
- PCDHA13 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV99170623; called by muse, mutect2, varscan2
- PCDHA4 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 205/634 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746844684, COSV63542556, COSV63543284; called by muse, mutect2, varscan2
- PCDHGB2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 239/697 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1561524605; called by muse, mutect2, varscan2
- PCNT | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749134992; called by muse, mutect2, varscan2
- PCNX3 | c.5562del p.V1855Wfs*29 | Frame Shift Del (DEL) | VAF 39/180 reads (22%) | catalogued as rs763360634; called by mutect2, pindel, varscan2
- PELI3 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs754046494; called by muse, mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PHF8 | c.3055C>T p.R1019C (on ENST00000357988 / NM_001184896.1; = p.R983C on NM_015107.3) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1271484888; called by muse, mutect2, varscan2
- PHRF1 | c.4052C>T p.A1351V (on ENST00000264555 / NM_001286581.2; = p.A1350V on NM_020901.4) | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs371787558; called by muse, mutect2, varscan2
- PIK3R1 | c.1196G>A p.S399N (on ENST00000521381 / NM_181523.3; = p.S129N on NM_181504.4) | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV57137237; called by muse, mutect2, varscan2
- PIP5K1C | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs891029085, COSV100095739; called by muse, mutect2, varscan2
- PKD1 | c.7552C>T p.R2518C | Missense Mutation (SNP) | VAF 266/886 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769524477, COSV51916028; called by muse, mutect2, varscan2
- PKD2L2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as rs766721598, COSV99296641; called by muse, mutect2, varscan2
- PKN3 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs571277935, COSV99403200; called by muse, mutect2, varscan2
- PLAG1 | c.1373del p.P458Hfs*13 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as COSV57610471; called by mutect2, varscan2
- PLCD3 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs999183937; called by muse, mutect2, varscan2
- PLCH2 | c.2399G>A p.C800Y | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1156783053; called by muse, mutect2, varscan2
- PLD1 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs749537417; called by muse, mutect2, varscan2
- PLEKHG1 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs754481715, COSV62045900; called by muse, mutect2, varscan2
- PLEKHG6 | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV50606502; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | catalogued as rs765091847; called by mutect2, varscan2
- PLPP4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs764089130, COSV64826946; called by muse, mutect2, varscan2
- PLVAP | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141514915; called by muse, mutect2, varscan2
- PLXNA4 | c.4780G>A p.V1594M | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs529500573, COSV58167212; called by muse, mutect2, varscan2
- PLXND1 | c.3078-3del | Splice Region (DEL) | VAF 32/152 reads (21%) | catalogued as rs1278682279; called by mutect2, pindel, varscan2
- PNPLA8 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs770894436; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV57965419; called by muse, mutect2, varscan2
- POLG | c.547del p.E183Rfs*83 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs35065786; called by mutect2, pindel, varscan2
- POLR2F | c.358del p.V120Wfs*159 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | catalogued as rs1293095997, COSV62807618; called by mutect2, pindel, varscan2
- PPARGC1A | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1419054523; called by muse, mutect2, varscan2
- PPP1R16B | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs1461549690, COSV55378060; called by muse, mutect2, varscan2
- PPP1R3D | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62564990; called by muse, mutect2, varscan2
- PRDM15 | c.3340G>A p.V1114I | Missense Mutation (SNP) | VAF 134/434 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs1162900974; called by muse, mutect2, varscan2
- PREX1 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV100906452; called by muse, mutect2, varscan2
- PRMT8 | c.504A>T p.K168N | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99713509; called by muse, mutect2, varscan2
- PROC | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 119/372 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1302897340, COSV99300660; called by muse, mutect2, varscan2
- PRPF8 | c.5110G>A p.A1704T | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs369956356; called by muse, mutect2
- PRR36 | c.1182del p.S395Rfs*8 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | catalogued as rs1267178456; called by mutect2, pindel, varscan2
- PRSS27 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs745462516; called by muse, mutect2
- PRTG | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs1237848846, COSV101221368; called by muse, mutect2, varscan2
- PSMA8 | c.102G>A p.A34= | Splice Region (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100379201, COSV57601028; called by muse, mutect2, varscan2
- PSMD4 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776886888; called by muse, mutect2, varscan2
- PTCH1 | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 163/463 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs145924695, CM135270; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- PTCHD3 | c.2057dup p.N686Kfs*6 | Frame Shift Ins (INS) | VAF 28/88 reads (32%) | catalogued as rs750923568; called by mutect2, varscan2
- PTH2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV54528818; called by muse, varscan2
- PTPN4 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55310470; called by muse, varscan2
- PTPRD | c.5666C>T p.T1889I | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs977043985; called by muse, mutect2, varscan2
- PWWP3A | c.1651del p.L551Wfs*31 (on ENST00000627377; = p.L550Wfs*31 on NM_032853.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1568953545; called by mutect2, pindel
- QSER1 | c.2421_2423del p.Q807del (on ENST00000399302; = p.Q936del on NM_001076786.3) | In Frame Del (DEL) | VAF 35/117 reads (30%) | catalogued as rs1394592478; called by pindel, varscan2
- RAB11FIP2 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62925067, COSV62925190; called by muse, mutect2, varscan2
- RAB42 | c.242dup p.V82Cfs*38 | Frame Shift Ins (INS) | VAF 32/131 reads (24%) | catalogued as rs753536519; called by mutect2, varscan2
- RAC3 | c.226-1G>A p.X76_splice | Splice Site (SNP) | VAF 79/270 reads (29%) | catalogued as rs756006325, COSV60712392; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | catalogued as rs767679528; called by mutect2, pindel
- RALGAPA2 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.922); catalogued as rs1482910750, COSV52513360; called by muse, mutect2, varscan2
- RCSD1 | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1310065421; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 53/184 reads (29%) | catalogued as rs762949421; called by mutect2, varscan2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIPK3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.791); catalogued as rs1416987664, COSV53475952; called by muse, mutect2, varscan2
- RNF207 | c.324+8C>T | Splice Region (SNP) | VAF 19/69 reads (28%) | catalogued as rs1456826041; called by muse, mutect2, varscan2
- RNF213 | c.14728G>A p.V4910M | Missense Mutation (SNP) | VAF 131/439 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774043685; called by muse, mutect2, varscan2
- RNF225 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); catalogued as rs951347423; called by mutect2, varscan2
- ROS1 | c.3500dup p.L1167Ffs*26 | Frame Shift Ins (INS) | VAF 44/202 reads (22%) | catalogued as rs748436511; called by mutect2, varscan2
- RP1L1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750002050, COSV66756869; ClinVar: benign; called by muse, mutect2, varscan2
- RRN3 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs746484179; called by muse, mutect2, varscan2
- RRP12 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs140714561; called by muse, mutect2, varscan2
- RYK | c.1504G>A p.G502R (on ENST00000620660 / NM_001005861.2; = p.G499R on NM_002958.4) | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253244411; called by muse, mutect2, varscan2
- RYR2 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1347807524; called by muse, mutect2, varscan2
- S1PR1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541724; called by muse, mutect2, varscan2
- SALL1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs761445962; called by muse, mutect2, varscan2
- SAMD4A | c.1621del p.R541Dfs*22 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs1566630333; called by mutect2, pindel
- SARDH | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1402325364, COSV64099325; called by muse, mutect2, varscan2
- SBNO2 | c.3791del p.P1264Rfs*89 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs1447461489, COSV62321793; called by mutect2, pindel, varscan2
- SCAF1 | c.1885C>T p.R629W | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1451832064; called by muse, varscan2
- SCMH1 | c.1838C>T p.A613V (on ENST00000326197 / NM_001031694.2; = p.A544V on NM_012236.4) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV58238460; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCUBE2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs771186135; called by muse, mutect2, varscan2
- SCYL2 | c.1297dup p.M433Nfs*11 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | catalogued as rs1555320617; called by mutect2, pindel, varscan2
- SELENOO | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs998589583; called by muse, mutect2
- SEMA4F | c.556dup p.X186_splice | Splice Site (INS) | VAF 20/77 reads (26%) | catalogued as rs749720924; called by mutect2, varscan2
- SETD1A | c.2769C>T p.D923= | Splice Region (SNP) | VAF 91/359 reads (25%) | catalogued as rs763265030; called by muse, mutect2, varscan2
- SETD6 | c.1009G>A p.E337K (on ENST00000219315 / NM_001160305.4; = p.E313K on NM_024860.3) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.471); catalogued as rs759939138; called by muse, mutect2, varscan2
- SEZ6L2 | c.1079G>A p.R360H (on ENST00000308713 / NM_001114099.3; = p.R290H on NM_012410.4) | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs774342907, COSV100435699; called by mutect2, varscan2
- SH3BGRL2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63964767; called by muse, mutect2, varscan2
- SIGLEC10 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 166/616 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.255); catalogued as rs1198803241; called by muse, mutect2
- SIRT5 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs201184922; called by muse, mutect2, varscan2
- SIX2 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 130/387 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs1201927647; called by muse, mutect2, varscan2
- SIX5 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1306935488; called by muse, mutect2, varscan2
- SKIV2L | c.2446del p.E816Rfs*3 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | catalogued as rs768446878; called by mutect2, pindel, varscan2
- SLC19A2 | c.1254A>C p.E418D | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV52547272; called by muse, mutect2, varscan2
- SLC22A31 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs781554563; called by muse, mutect2, varscan2
- SLC26A4 | c.965del p.N322Ifs*22 | Frame Shift Del (DEL) | VAF 99/324 reads (31%) | catalogued as rs747834704; called by mutect2, varscan2
- SLC26A6 | c.1618del p.V540* | Frame Shift Del (DEL) | VAF 65/334 reads (19%) | catalogued as rs780816364, COSV56576227; called by mutect2, pindel, varscan2
- SLC27A1 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs138631017; called by muse, mutect2, varscan2
- SLC2A8 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144114324; called by muse, mutect2, varscan2
- SLC52A2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 169/534 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as rs374006728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2062G>A p.G688S (on ENST00000540229 / NM_001371097.1; = p.G627S on NM_001009562.4) | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as rs112108376; called by muse, mutect2, varscan2
- SLITRK3 | c.2683T>G p.C895G | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.05); catalogued as rs754180450; called by muse, mutect2, varscan2
- SLTM | c.1460del p.N487Ifs*35 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs762322084; called by mutect2, varscan2
- SMC3 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 59/226 reads (26%) | catalogued as CM148621; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 82/262 reads (31%) | catalogued as rs747405143; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | catalogued as rs768873484; called by mutect2, varscan2
- SOBP | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 178/551 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766725468; called by muse, mutect2, varscan2
- SPARC | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.284); catalogued as rs532217814, COSV50557744; called by muse, mutect2, varscan2
- SPAST | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1412403865, COSV100188186; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEM2 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs113604978, COSV60366859; called by muse, mutect2
- SPTBN5 | c.6265C>T p.R2089C | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs778638478, COSV58019139; called by muse, mutect2, varscan2
- SPTBN5 | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 111/374 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.098); catalogued as rs1279166003, COSV58020956; called by muse, varscan2
- SREBF1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs913723079, COSV55415826; called by muse, mutect2, varscan2
- SRRM5 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375056368; called by muse, mutect2, varscan2
- SRSF7 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV57447443; called by muse, mutect2, varscan2
- SSC5D | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs777751220; called by muse, mutect2, varscan2
- SSTR5 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772503899; called by muse, mutect2, varscan2
- ST14 | c.2354C>T p.T785M | Missense Mutation (SNP) | VAF 162/472 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751188491, COSV53832504; called by muse, mutect2, varscan2
- STAB2 | c.7120C>T p.R2374W | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs112523896, COSV66342005; called by muse, mutect2, varscan2
- STON2 | c.2362C>T p.R788C (on ENST00000649389 / NM_001366849.2; = p.R731C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs771862629; called by muse, mutect2, varscan2
- STX1A | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 52/156 reads (33%) | catalogued as COSV99767510; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNE1 | c.8779C>T p.R2927C (on ENST00000367255 / NM_182961.4; = p.R2934C on NM_033071.3) | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs372633466; called by muse, mutect2, varscan2
- SZT2 | c.8930C>T p.P2977L (on ENST00000634258 / NM_001365999.1; = p.P2920L on NM_015284.4) | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs761830930, COSV65094821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.7625C>T p.P2542L (on ENST00000334433; = p.P620L on NM_006997.4) | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs369295547; called by muse, mutect2, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs749363736; called by mutect2, pindel, varscan2
- TAF5L | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 174/558 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs200127796, COSV51081847; called by muse, mutect2, varscan2
- TAOK1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1249095811, COSV55601117; called by muse, mutect2, varscan2
- TAS2R16 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.345); catalogued as COSV99972356; called by muse, mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 158/551 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TECPR2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs2295973, COSV63971267; called by muse, mutect2, varscan2
- TEKT2 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 145/495 reads (29%) | catalogued as rs756817003; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 59/160 reads (37%) | catalogued as rs771515402; called by mutect2, varscan2
- TICAM1 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1294358833; called by muse, mutect2, varscan2
- TIMELESS | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as rs1203173297, COSV57512727; called by muse, mutect2
- TLE6 | c.1637C>T p.T546M (on ENST00000246112 / NM_001143986.2; = p.T423M on NM_024760.3) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs146997057; called by muse, varscan2
- TLL1 | c.2883del p.G963Vfs*20 | Frame Shift Del (DEL) | VAF 62/328 reads (19%) | catalogued as COSV50325027, COSV50327204; called by mutect2, pindel, varscan2
- TMEM104 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs768576277, COSV100120792; called by muse, mutect2, varscan2
- TMEM104 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs755776375, COSV59107629; called by muse, mutect2, varscan2
- TMEM117 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs772555669, COSV56898989, COSV56899483; called by muse, mutect2, varscan2
- TMEM200C | c.62dup p.S22Kfs*66 | Frame Shift Ins (INS) | VAF 56/200 reads (28%) | catalogued as rs756579008; called by mutect2, pindel, varscan2
- TMEM262 | c.22G>A p.A8T (on ENST00000530719 / NM_001282448.1; = p.A6T on NM_001242631.2) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as rs568583876, COSV51871016; called by muse, mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TPRA1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318022042, COSV56160642; called by muse, mutect2, varscan2
- TPTE | c.665G>A p.R222Q (on ENST00000618007 / NM_199261.4; = p.R204Q on NM_199259.4) | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs530503790; called by muse, mutect2, varscan2
- TRAM1L1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527665848; called by muse, mutect2, varscan2
- TRAV19 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs774931881; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIM7 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.59); catalogued as rs770769065; called by muse, mutect2, varscan2
- TSC2 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs745897413, COSV54764746; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TSKU | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1001756036, COSV100290116; called by muse, mutect2, varscan2
- TSPYL6 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57813497; called by muse, mutect2, varscan2
- TTC30A | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs776398080, COSV53696374; called by muse, mutect2, varscan2
- TTC37 | c.4480C>T p.R1494C | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373485467; called by muse, mutect2, varscan2
- TTN | c.99989C>T p.A33330V (on ENST00000591111; = p.A25906V on NM_003319.4) | Missense Mutation (SNP) | VAF 101/326 reads (31%) | PolyPhen possibly damaging (0.677); catalogued as rs1419052992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP1L | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV72399580; called by muse, mutect2, varscan2
- UBE4B | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs777945500; called by muse, mutect2, varscan2
- UBQLN3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs370344868, COSV61163760; called by muse, mutect2, varscan2
- UBR5 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs1260190339, COSV99642645; called by muse, mutect2, varscan2
- UGT1A6 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765612353, COSV59388562, COSV59399731; called by muse, mutect2, varscan2
- UGT2B27P | n.901T>C | Splice Region (SNP) | VAF 56/245 reads (23%) | catalogued as rs761422700; called by muse, mutect2, varscan2
- UHRF1BP1L | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367741405; called by muse, varscan2
- UNC13D | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 144/478 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs760020541, COSV99257835; called by muse, mutect2, varscan2
- USP25 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 13/290 reads (4%) | catalogued as COSV53482443; called by muse, mutect2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 76/202 reads (38%) | catalogued as rs761320003; called by mutect2, varscan2
- USP46 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV71512636; called by muse, mutect2, varscan2
- USP54 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770341500; called by muse, mutect2, varscan2
- VAC14 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs369652478; called by muse, mutect2, varscan2
- VASP | c.551dup p.P185Tfs*70 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | catalogued as rs762759767; called by mutect2, varscan2
- VIRMA | c.2942G>A p.S981N | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99889424; called by muse, mutect2, varscan2
- VOPP1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs763651805; called by muse, mutect2, varscan2
- VPS8 | c.4206G>T p.Q1402H (on ENST00000625842 / NM_001349294.1; = p.Q1400H on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54993043; called by muse, mutect2
- VWA8 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); catalogued as COSV55701994, COSV99863856; called by muse, mutect2, varscan2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 32/174 reads (18%) | catalogued as rs780890680; called by mutect2, varscan2
- WDR90 | c.4141G>A p.A1381T | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as rs756807276; called by muse, mutect2, varscan2
- WIZ | c.4450G>A p.A1484T (on ENST00000673675 / NM_001371589.1; = p.A389T on NM_021241.3) | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879252345; called by muse, mutect2, varscan2
- WIZ | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.399); catalogued as rs868130258; called by muse, mutect2, varscan2
- WNK4 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 110/365 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs1188965960, COSV99891731; called by muse, mutect2, varscan2
- WNT9A | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 164/557 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777836213, COSV55295816; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 106/364 reads (29%) | catalogued as rs762052135; called by mutect2, varscan2
- ZAN | c.4721C>T p.S1574F | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.092); catalogued as rs1562938710, COSV100769740; called by muse, mutect2, varscan2
- ZBTB17 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1210459439; called by muse, mutect2, varscan2
- ZBTB20 | c.490C>T p.R164W (on ENST00000474710 / NM_001164342.2; = p.R91W on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779425353, COSV61850207; called by muse, mutect2, varscan2
- ZBTB4 | c.11del p.P4Lfs*4 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs765991494; called by mutect2, varscan2
- ZC3H12A | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.035); catalogued as COSV100897616; called by muse, mutect2, varscan2
- ZC3H12D | c.967del p.R323Gfs*175 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as rs1374931227; called by mutect2, pindel, varscan2
- ZFP91 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 132/458 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs747867221; called by muse, mutect2, varscan2
- ZIK1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100277555; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072del p.N691Mfs*12 | Frame Shift Del (DEL) | VAF 100/366 reads (27%) | catalogued as rs556762260; called by mutect2, pindel, varscan2
- ZNF12 | c.1679A>G p.Q560R (on ENST00000405858 / NM_016265.4; = p.Q522R on NM_006956.3) | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.298); catalogued as rs758514915; called by muse, mutect2, varscan2
- ZNF141 | c.1162del p.I388Ffs*51 | Frame Shift Del (DEL) | VAF 92/319 reads (29%) | catalogued as rs782618581; called by mutect2, pindel, varscan2
- ZNF142 | c.2846A>G p.D949G (on ENST00000411696 / NM_001379660.1; = p.D749G on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV68743150; called by muse, mutect2
- ZNF143 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1394297185, COSV55182862; called by muse, mutect2, varscan2
- ZNF19 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs752489954; called by muse, mutect2, varscan2
- ZNF205 | c.1619C>G p.A540G | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV54620238, COSV54620780; called by muse, mutect2, varscan2
- ZNF296 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as rs1222514229; called by muse, mutect2, varscan2
- ZNF324B | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773775264; called by muse, mutect2
- ZNF425 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs760572027, COSV65200504; called by muse, mutect2, varscan2
- ZNF43 | c.752dup p.N251Kfs*4 | Frame Shift Ins (INS) | VAF 23/134 reads (17%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF462 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs538337965, COSV99470857; called by muse, mutect2, varscan2
- ZNF467 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs771215784; called by muse, mutect2, varscan2
- ZNF521 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.786); catalogued as rs1290075311; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 67/183 reads (37%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF653 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs374324752; called by muse, mutect2, varscan2
- ZNF705G | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 159/781 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as rs548952183, COSV67951115; called by muse, mutect2, varscan2
- ZNF831 | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374820470; called by muse, mutect2, varscan2
- ZRSR2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 72/254 reads (28%) | catalogued as rs775221448, COSV57063728; called by muse, mutect2, varscan2
- A2M | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AASDH | c.342del p.K114Nfs*14 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, varscan2
- ABCA2 | c.13del p.T5Rfs*77 | Frame Shift Del (DEL) | VAF 65/219 reads (30%) | called by mutect2, pindel, varscan2
- ABHD1 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2
- ABHD10 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD13 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ABL2 | c.1465A>T p.I489F (on ENST00000502732 / NM_007314.4; = p.I474F on NM_005158.5) | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ABO | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 234/758 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AC069544.2 | c.1066A>T p.I356F | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AC092143.1 | c.1858del p.L620Sfs*12 | Frame Shift Del (DEL) | VAF 239/885 reads (27%) | called by mutect2, pindel, varscan2
- ACSL6 | c.1762G>A p.V588I (on ENST00000379240; = p.V613I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ACVRL1 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS13 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ADAP1 | c.1007_1012dup p.F336_A337dup | In Frame Ins (INS) | VAF 129/476 reads (27%) | called by mutect2, varscan2
- ADGRA2 | c.3277dup p.H1093Pfs*173 | Frame Shift Ins (INS) | VAF 45/193 reads (23%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 40/202 reads (20%) | called by pindel, varscan2
- ADK | c.199G>A p.D67N (on ENST00000286621; = p.D50N on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- ADSL | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AFF3 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGRN | c.5321T>C p.L1774P | Missense Mutation (SNP) | VAF 158/501 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.15463del p.I5155* | Frame Shift Del (DEL) | VAF 58/208 reads (28%) | called by mutect2, pindel, varscan2
- AHNAK | c.3497C>A p.A1166D | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- AHNAK2 | c.7081C>T p.L2361F | Missense Mutation (SNP) | VAF 101/720 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AJM1 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 16/530 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- AKIRIN1 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- AL592490.1 | c.347del p.P116Lfs*11 | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | called by mutect2, pindel, varscan2
- ALDH4A1 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 132/439 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ALOX15B | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 159/520 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 24/248 reads (10%) | called by mutect2, pindel
- AMIGO3 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 19/640 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); called by muse, mutect2
- AMY2B | c.1417del p.I473Lfs*42 | Frame Shift Del (DEL) | VAF 145/560 reads (26%) | called by mutect2, pindel, varscan2
- ANKDD1A | c.1556A>G p.Q519R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKEF1 | c.1269del p.G424Efs*32 | Frame Shift Del (DEL) | VAF 57/199 reads (29%) | called by mutect2, pindel, varscan2
- ANKLE1 | c.1939C>A p.R647S (on ENST00000394458; = p.R593S on NM_152363.6) | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANKRD26 | c.3702del p.K1234Nfs*19 | Frame Shift Del (DEL) | VAF 64/190 reads (34%) | called by mutect2, varscan2
- ANKRD50 | c.3263dup p.N1088Kfs*8 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | called by mutect2, pindel, varscan2
- ANKRD53 | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANKRD65 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- ANO9 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APLP1 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AREL1 | c.294_295del p.R99Sfs*40 | Frame Shift Del (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.2842A>G p.M948V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARHGAP30 | c.2826del p.K943Sfs*61 (on ENST00000368013 / NM_001025598.2; = p.K732Sfs*61 on NM_181720.3) | Frame Shift Del (DEL) | VAF 101/345 reads (29%) | called by mutect2, pindel, varscan2
- ARID1A | c.3281del p.K1094Sfs*67 | Frame Shift Del (DEL) | VAF 117/408 reads (29%) | called by mutect2, pindel, varscan2
- ARL6 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ASCC3 | c.2079G>T p.K693N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ASTE1 | c.498del p.F166Lfs*3 | Frame Shift Del (DEL) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
- ATAD5 | c.2910del p.K970Nfs*32 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- ATP11A | c.455T>A p.V152D | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP11A | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ATP5IF1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- ATXN10 | c.517del p.I173Lfs*7 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- AXIN2 | c.1442T>G p.L481R | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 258/780 reads (33%) | called by pindel, varscan2
- B2M | c.204del p.V69Wfs*34 | Frame Shift Del (DEL) | VAF 71/395 reads (18%) | called by mutect2, pindel, varscan2
- BACE1 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BAHCC1 | c.1153del p.R385Gfs*3 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.5100G>T p.K1700N | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 95/298 reads (32%) | called by mutect2, pindel, varscan2
- BIN1 | c.79_81del p.E27del | In Frame Del (DEL) | VAF 104/307 reads (34%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.3710A>G p.Y1237C | Missense Mutation (SNP) | VAF 143/452 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BLK | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BMP10 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C12orf40 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf46 | c.116del p.N39Ifs*56 | Frame Shift Del (DEL) | VAF 51/204 reads (25%) | called by mutect2, pindel, varscan2
- C1QA | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- C1orf159 | c.596del p.P199Rfs*82 (on ENST00000379339 / NM_001330306.2; = p.P163Rfs*96 on NM_017891.5) | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- C20orf144 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 159/469 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C21orf58 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C7 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1I | c.1422del p.A475Pfs*173 | Frame Shift Del (DEL) | VAF 39/190 reads (21%) | called by mutect2, pindel, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | called by mutect2, pindel, varscan2
- CAGE1 | c.1962del p.K654Nfs*2 (on ENST00000512086; = p.K518Nfs*2 on NM_205864.3) | Frame Shift Del (DEL) | VAF 63/183 reads (34%) | called by mutect2, pindel, varscan2
- CALML5 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 156/587 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CANX | c.1304_1305del p.F435* | Frame Shift Del (DEL) | VAF 80/329 reads (24%) | called by pindel, varscan2
- CAPG | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- CAPN9 | c.1330del p.A444Pfs*9 | Frame Shift Del (DEL) | VAF 126/474 reads (27%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.1615_1616del p.L539Gfs*52 | Frame Shift Del (DEL) | VAF 72/304 reads (24%) | called by pindel, varscan2
- CARMIL2 | c.1831C>A p.L611M | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASP2 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX2 | c.1532A>G p.N511S | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CBX6 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC105 | c.20del p.P7Rfs*29 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- CCDC73 | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- CD22 | c.2363del p.P788Rfs*38 | Frame Shift Del (DEL) | VAF 74/330 reads (22%) | called by mutect2, pindel, varscan2
- CDC42EP5 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH12 | c.234C>T p.L78= | Splice Region (SNP) | VAF 20/72 reads (28%) | called by muse, varscan2
- CDH26 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CDYL2 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CELSR1 | c.6085_6102del p.I2029_N2034del | In Frame Del (DEL) | VAF 72/264 reads (27%) | called by mutect2, pindel, varscan2
- CELSR2 | c.4256T>C p.L1419P | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CENPI | c.975del p.E326Rfs*2 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CEP128 | c.1242del p.K414Nfs*34 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, pindel, varscan2
- CEP152 | c.3806A>G p.Q1269R (on ENST00000380950 / NM_001194998.2; = p.Q1213R on NM_014985.4) | Missense Mutation (SNP) | VAF 20/455 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CFAP410 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.761G>C p.C254S | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CFAP54 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP65 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- CHD7 | c.1045A>G p.N349D | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHFR | c.1312G>A p.A438T (on ENST00000432561 / NM_001161345.1; = p.A397T on NM_018223.2) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CHRNB1 | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 113/480 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIP2A | c.667del p.E223Kfs*15 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- CLIP3 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CLSTN2 | c.2702C>G p.T901S | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLUH | c.1075G>A p.E359K (on ENST00000435359; = p.E397K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CMYA5 | c.11310dup p.E3771* | Frame Shift Ins (INS) | VAF 35/130 reads (27%) | called by mutect2, pindel, varscan2
- CNOT7 | c.375dup p.H126Tfs*2 | Frame Shift Ins (INS) | VAF 37/161 reads (23%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.2350T>C p.S784P | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL4A2 | c.3598G>T p.G1200C | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO7 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CPN2 | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CPXM1 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CRCT1 | c.239del p.G80Afs*62 | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by mutect2, pindel, varscan2
- CRY2 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSNK1G1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CUL4A | c.731C>A p.A244D (on ENST00000375440 / NM_001008895.4; = p.A144D on NM_003589.3) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CXCL17 | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- CXXC5 | c.168del p.E57Sfs*40 | Frame Shift Del (DEL) | VAF 81/284 reads (29%) | called by mutect2, pindel, varscan2
- CYB5R3 | c.830del p.P277Hfs*3 | Frame Shift Del (DEL) | VAF 101/365 reads (28%) | called by mutect2, pindel, varscan2
- DAB2IP | c.2811del p.N938Tfs*3 (on ENST00000408936; = p.N910Tfs*3 on NM_032552.3) | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- DCAF15 | c.1419C>G p.D473E | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- DCAF17 | c.989dup p.N330Kfs*14 | Frame Shift Ins (INS) | VAF 29/181 reads (16%) | called by mutect2, pindel, varscan2
- DCTN1 | c.2878A>G p.K960E | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DDX10 | c.1199T>C p.I400T | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX10 | c.2028dup p.V677Sfs*7 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | called by mutect2, varscan2
- DDX5 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- DDX59 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- DENND2C | c.2390A>T p.E797V (on ENST00000393274 / NM_001256404.2; = p.E740V on NM_198459.4) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- DENND4B | c.3503A>T p.Y1168F | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DENND6A | c.1105_1107del p.I369del | In Frame Del (DEL) | VAF 35/136 reads (26%) | called by pindel, varscan2
- DEPDC4 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DHX34 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 129/436 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DHX36 | c.578dup p.N193Kfs*2 | Frame Shift Ins (INS) | VAF 19/80 reads (24%) | called by mutect2, varscan2
- DIAPH3 | c.3497dup p.E1167Gfs*10 | Frame Shift Ins (INS) | VAF 93/356 reads (26%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.1393G>C p.V465L (on ENST00000400324 / NM_001042517.2; = p.V202L on NM_030932.3) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DIP2A | c.3404dup p.K1136Efs*49 | Frame Shift Ins (INS) | VAF 81/260 reads (31%) | called by mutect2, varscan2
- DLGAP1 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP1 | c.1688_1689del p.T563Rfs*58 | Frame Shift Del (DEL) | VAF 112/412 reads (27%) | called by pindel, varscan2
- DLGAP2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLGAP3 | c.1827del p.T610Hfs*68 | Frame Shift Del (DEL) | VAF 78/278 reads (28%) | called by mutect2, pindel, varscan2
- DMD | c.8404G>C p.A2802P | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- DMRT1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMWD | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DNA2 | c.2494A>T p.K832* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | called by muse, varscan2
- DNA2 | c.2462T>C p.V821A | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | called by mutect2, pindel, varscan2
- DNAJC5B | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2
- DNLZ | c.510dup p.S171Qfs*66 | Frame Shift Ins (INS) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- DNMBP | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- DOCK6 | c.4327C>A p.L1443I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DPT | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DPYSL2 | c.60dup p.K21* | Frame Shift Ins (INS) | VAF 38/98 reads (39%) | called by mutect2, varscan2
- DUOX1 | c.3436G>T p.V1146L | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUSP23 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DYNC1LI2 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); called by muse, varscan2
- DYNC2H1 | c.7077del p.D2360Ifs*16 | Frame Shift Del (DEL) | VAF 78/282 reads (28%) | called by mutect2, pindel, varscan2
- DZIP1 | c.736T>A p.L246M | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F2 | c.349A>G p.S117G | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EDN3 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEA1 | c.3605del p.K1202Rfs*6 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.3461G>C p.G1154A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- EIF3I | c.130_131del p.R44Afs*17 | Frame Shift Del (DEL) | VAF 88/335 reads (26%) | called by pindel, varscan2
- EIF3J | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.019); called by mutect2, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, varscan2
- EIF4H | c.123del p.Y42Tfs*5 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by pindel, varscan2
- ELL | c.1783T>C p.C595R | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML2 | c.710del p.G237Afs*3 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | called by mutect2, pindel, varscan2
- ENGASE | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EPPK1 | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ERCC3 | c.1352T>A p.F451Y | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- ERRFI1 | c.419T>C p.F140S | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ESYT3 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESYT3 | c.2036T>C p.I679T | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- ETV3 | c.1468A>C p.S490R | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVA1B | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 172/521 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM110A | c.154A>C p.K52Q | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM114A1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM120A | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM187B | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM200A | c.702_704del p.N235del | In Frame Del (DEL) | VAF 35/120 reads (29%) | called by pindel, varscan2
- FAM83G | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FBLL1 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBRSL1 | c.1720del p.V574Wfs*6 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | called by mutect2, pindel, varscan2
- FBXL4 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXL7 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 105/359 reads (29%) | called by muse, varscan2
- FCGBP | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FCHO1 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FDFT1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); called by muse, mutect2
- FER1L6 | c.5330_5332del p.E1777del | In Frame Del (DEL) | VAF 40/182 reads (22%) | called by pindel, varscan2
- FIZ1 | c.921del p.L308Cfs*182 | Frame Shift Del (DEL) | VAF 70/272 reads (26%) | called by mutect2, pindel, varscan2
- FKBP4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FLYWCH2 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FOXA1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXK2 | c.643del p.R215Gfs*13 | Frame Shift Del (DEL) | VAF 37/127 reads (29%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.1850dup p.L617Ffs*24 | Frame Shift Ins (INS) | VAF 97/335 reads (29%) | called by mutect2, pindel, varscan2
- FTSJ1 | c.326dup p.A110Cfs*7 | Frame Shift Ins (INS) | VAF 19/177 reads (11%) | called by mutect2, pindel, varscan2
- FUT2 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 118/379 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FUZ | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 144/508 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- G3BP2 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.313); called by muse, mutect2
852 further variants in this file (357 protein-altering or splice-affecting, 282 silent, 213 other) are not listed here.
